Somatic mutation profile of tumor specimen ALCH-B0AM-TTP1-A (aliquot ALCH-B0AM-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0AM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,702 days).
Specimen ALCH-B0AM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a0348f1-9aa6-4b63-bf4b-098b344bea71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AM-NB1-A (Blood Derived Normal), aliquot ALCH-B0AM-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fab5bf11-e1bd-43b5-8778-32761d4feeea

The open-access MAF lists 44 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Splice Site 2, Intron 2, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 286/601 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 333/706 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs560787141, COSV100879356, COSV66105839; called by muse, mutect2, varscan2
- AC026464.6 | c.401A>C p.Q134P | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54750802; called by muse, mutect2, varscan2
- CDIPT | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99570160; called by muse, mutect2, varscan2
- JPH2 | c.1354C>G p.P452A | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1440920206, COSV65904427; called by muse, mutect2, varscan2
- KCMF1 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773388864; called by muse, mutect2, varscan2
- SMO | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50826393; called by muse, mutect2, varscan2
- APOB | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 187/629 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- BAP1 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 196/523 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- BTNL9 | c.956-1G>A p.X319_splice | Splice Site (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- CRIP2 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIAPH3 | c.328A>T p.M110L | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, varscan2
- EVI5L | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FBXO45 | c.127_141del p.V43_V47del | In Frame Del (DEL) | VAF 24/154 reads (16%) | called by mutect2, pindel
- KCNV2 | c.911A>T p.H304L | Missense Mutation (SNP) | VAF 143/413 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KDM1B | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K9 | c.2687T>G p.L896R (on ENST00000554752 / NM_001284230.1; = p.L910R on NM_033141.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MTOR | c.1636G>T p.V546F | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- OR5A1 | c.418A>C p.T140P | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCQ | c.1153dup p.M385Nfs*37 | Frame Shift Ins (INS) | VAF 22/237 reads (9%) | called by mutect2, pindel
- PSMD10 | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 88/158 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- RALGAPB | c.872+1G>A p.X291_splice | Splice Site (SNP) | VAF 52/123 reads (42%) | called by mutect2, varscan2
- RFXAP | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TNFRSF10B | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 15/408 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.13); called by muse, mutect2
- TRBV23-1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 18/425 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); called by muse, mutect2
- TRIM23 | c.1691A>T p.Q564L | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TTC27 | c.1159T>G p.S387A | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAT2 | c.711C>T p.T237= | Silent (SNP) | VAF 57/172 reads (33%) | catalogued as rs780991485; called by muse, mutect2, varscan2
- C4orf50 | c.310C>T p.L104= (on ENST00000324058; = p.L1336= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2
- CORIN | c.1884A>G p.K628= | Silent (SNP) | VAF 48/229 reads (21%) | called by muse, mutect2, varscan2
- FBXO33 | c.888T>A p.L296= | Silent (SNP) | VAF 101/293 reads (34%) | called by muse, mutect2, varscan2
- KNDC1 | c.273G>A p.G91= | Silent (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- KRTAP6-1 | c.66C>T p.G22= | Silent (SNP) | VAF 108/385 reads (28%) | called by muse, mutect2, varscan2
- MED26 | c.1608G>A p.P536= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as rs200454256; called by muse, mutect2, varscan2
- MNX1 | c.822G>A p.V274= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as rs1458009766; called by muse, mutect2
- MSL3 | c.1494C>T p.F498= (on ENST00000312196 / NM_078629.4; = p.F332= on NM_006800.4) | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1569097741, COSV100384523, COSV56492058; called by muse, mutect2, varscan2
- NAP1L5 | c.72G>A p.E24= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs1264033075; called by muse, mutect2, varscan2
- PDGFRA | c.738A>G p.Q246= | Silent (SNP) | VAF 28/587 reads (5%) | catalogued as rs377699966; ClinVar: likely benign; called by muse, mutect2
- RASGEF1A | c.582G>T p.G194= | Silent (SNP) | VAF 38/448 reads (8%) | called by muse, mutect2
- RCC1 | c.84G>A p.R28= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- KRT18 | c.-33C>G | 5'UTR (SNP) | VAF 36/136 reads (26%) | catalogued as COSV66315740, COSV66316457; called by muse, mutect2, varscan2
- RACK1 | c.889-258A>G | Intron (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- UACA | c.79-2222A>G | Intron (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
